Gene-level copy-number profile of tumor specimen TCGA-ZP-A9CY-01A from TCGA case TCGA-ZP-A9CY, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 66.3 years (24,223 days).
Specimen TCGA-ZP-A9CY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.da83586a-75ed-45c8-b79f-6d981d5c2b93.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZP-A9CY-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9ea733fe-e6ea-4658-8ca3-ecef2e2ad3d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 664; copy number 2: 57,988; copy number 3: 1,086; copy number 4: 75; copy number 5: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZP-A9CY-01A-11D-A381-01): tumor purity 0.73, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:57,953,424–58,497,866, 1 gene, copy number 5 (within-gene range 2–5): ALDH1A2.
- chr15:58,410,569–58,591,676, 6 genes, copy number 5: LIPC, LIPC-AS1, AC084781.1, AC084781.2, AC018904.2, AC018904.1.

Autosomal genes at a single copy (total copy number 1): 664. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
